Somatic mutation profile of tumor specimen TCGA-A2-A0YD-01A (aliquot TCGA-A2-A0YD-01A-11D-A10G-09) from TCGA case TCGA-A2-A0YD, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 63.0 years (23,021 days).
Specimen TCGA-A2-A0YD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a5ff1bb-821a-42b5-8999-bf2c778cf1f0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0YD-10A (Blood Derived Normal), aliquot TCGA-A2-A0YD-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b890d1a6-0c7b-4e9c-bdc8-846d73ffe9e0

The open-access MAF lists 64 somatic variants for this specimen: 43 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 20, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPC1 | c.3493G>A p.V1165M | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748862167, CM015193, COSV52571405; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC11 | c.3667C>G p.Q1223E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62323087; called by muse, mutect2, varscan2
- AKAP12 | c.3718G>A p.E1240K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99482147; called by muse, mutect2
- AKAP13 | c.4555G>A p.E1519K | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100774101, COSV63363181; called by muse, mutect2, varscan2
- BAP1 | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as rs1270349297, COSV56239921; called by muse, mutect2
- C1QB | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233712190, COSV100152720, COSV59245358; called by muse, mutect2, varscan2
- CAD | c.6149G>A p.G2050E | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1232626604, COSV53026835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMSAP2 | c.2559G>C p.E853D (on ENST00000236925 / NM_001297707.2; = p.E842D on NM_203459.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs1170360826, COSV99372691; called by mutect2, varscan2
- CCDC183 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as COSV99264342; called by muse, varscan2
- CCDC183 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as rs1304544487, COSV61035623; called by muse, mutect2, varscan2
- CCDC183 | c.1150G>C p.E384Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.076); catalogued as rs1564352447, COSV61035627; called by muse, mutect2, varscan2
- CD5 | c.174G>A p.M58I | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as COSV61718396; called by muse, mutect2, varscan2
- CDKL4 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV66509602; called by muse, mutect2, varscan2
- CSMD3 | c.1340G>C p.R447T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV52167613, COSV99820440; called by muse, varscan2
- CTNNBL1 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs760728264, COSV63744813; called by muse, mutect2, varscan2
- DNAH5 | c.8384G>A p.R2795Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99443203; called by muse, mutect2, varscan2
- F11R | c.282C>G p.I94M | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV57037488, COSV57037537; called by muse, mutect2, varscan2
- FAM120C | c.2083G>C p.E695Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60259386, COSV60263425; called by muse, mutect2, varscan2
- FUBP1 | c.32C>A p.S11Y | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV53931198, COSV53931469; called by muse, mutect2, varscan2
- GRIA3 | c.1529C>G p.T510S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); catalogued as COSV52059636; called by muse, mutect2, varscan2
- ITPKB | c.2029G>A p.A677T | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as rs1336927158, COSV55258343; called by muse, mutect2, varscan2
- MAGEC3 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.679); catalogued as COSV53580256; called by muse, mutect2, varscan2
- MITF | c.853C>T p.P285S (on ENST00000448226 / NM_006722.3; = p.P179S on NM_000248.4) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV100096287, COSV58831808; called by muse, mutect2, varscan2
- MXRA5 | c.1417G>A p.G473S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1308414920, COSV54235003; called by muse, mutect2, varscan2
- NF1 | c.3198-1G>A p.X1066_splice | Splice Site (SNP) | VAF 6/10 reads (60%) | catalogued as rs1223905930, COSV62206676, COSV62214320, COSV62215374; called by mutect2, varscan2
- NOLC1 | c.1078G>C p.E360Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.795); catalogued as rs747818823, COSV64180452; called by muse, mutect2, varscan2
- OR10X1 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV63767278; called by muse, mutect2
- PKD1 | c.5722C>T p.Q1908* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as CM1110561, COSV51916231; called by muse, mutect2
- PLXNA2 | c.2347G>A p.V783M | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.668); catalogued as COSV65440687; called by muse, mutect2, varscan2
- PPP4C | c.357G>C p.Q119H | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV54221950; called by muse, mutect2, varscan2
- PTDSS2 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57278153; called by muse, mutect2, varscan2
- SPATS2L | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV100660383, COSV62352311; called by muse, mutect2, varscan2
- SPON1 | c.494A>C p.Q165P | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100115041; called by muse, mutect2
- TMEM104 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as rs535487037, COSV59109460; called by muse, mutect2, varscan2
- TRAPPC2L | c.294+1G>A p.X98_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as rs372192905, COSV51937616; called by muse, mutect2, varscan2
- TRMT2A | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV52813439; called by muse, mutect2, varscan2
- UBOX5 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV53906110; called by muse, mutect2, varscan2
- VPS4A | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.595); catalogued as rs757227102, COSV99651786; called by muse, mutect2, varscan2
- ZNF503 | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65307661; called by muse, mutect2, varscan2
- CDH1 | c.1016del p.P339Lfs*17 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | called by mutect2, pindel, varscan2
- CYFIP2 | c.3662_3665del p.K1221Mfs*4 (on ENST00000616178 / NM_001291722.2; = p.K1196Mfs*4 on NM_014376.4) | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.3646dup p.I1216Nfs*23 | Frame Shift Ins (INS) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- MUC2 | c.2744C>T p.S915L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- ACTN1 | c.276C>T p.N92= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as rs780296951, COSV51991776; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALDH9A1 | c.93C>T p.V31= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs1426295570, COSV61339857; called by muse, mutect2
- B3GALNT1 | c.84G>C p.L28= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs199813560, COSV100251886; called by muse, mutect2, varscan2
- BRINP1 | c.1704C>T p.S568= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs894094116, COSV56299857, COSV56314649; called by muse, mutect2
- C1orf127 | c.615G>A p.L205= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as COSV65437066; called by muse, mutect2, varscan2
- C1orf56 | c.864C>T p.P288= | Silent (SNP) | VAF 30/223 reads (13%) | catalogued as COSV99764476; called by muse, mutect2, varscan2
- CALN1 | c.15G>A p.E5= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as rs938403661, COSV67951255; called by muse, varscan2
- CTSG | c.180G>A p.L60= | Silent (SNP) | VAF 20/106 reads (19%) | catalogued as COSV53535462; called by muse, mutect2, varscan2
- FAT3 | c.7515G>A p.V2505= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99959828; called by muse, mutect2
- MUC5B | c.2145G>A p.L715= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV71592050; called by muse, mutect2, varscan2
- OR52N5 | c.252C>T p.T84= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV57698865; called by muse, mutect2, varscan2
- RIMBP2 | c.2913C>T p.N971= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs535947066, COSV55472412; called by mutect2, varscan2
- RORB | c.1281C>T p.I427= (on ENST00000396204 / NM_001365023.1; = p.I416= on NM_006914.4) | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV65335893; called by muse, mutect2, varscan2
- SPTY2D1 | c.1212C>T p.S404= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1489210394, COSV60473818; called by muse, mutect2, varscan2
- STAC3 | c.867C>T p.I289= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV60414003; called by muse, mutect2, varscan2
- TMEM141 | c.273C>G p.L91= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV51567053; called by muse, mutect2, varscan2
- TXNIP | c.198T>C p.T66= | Silent (SNP) | VAF 58/151 reads (38%) | catalogued as rs1334538213, COSV65220528; called by muse, mutect2, varscan2
- XKR7 | c.1569C>T p.I523= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1397350459, COSV101629223; called by muse, mutect2
- ZDHHC20 | c.1008C>T p.D336= (on ENST00000400590 / NM_001330059.2; = p.D335= on NM_153251.3) | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV57185878; called by muse, mutect2, varscan2
- ZNFX1 | c.1996C>T p.L666= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV65575457; called by muse, mutect2, varscan2
- RPGR | c.2520+156G>C | Intron (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100139439; called by muse, mutect2, varscan2
